Somatic mutation profile of tumor specimen MP2PRT-PAVKYE-TMP1-A (aliquot MP2PRT-PAVKYE-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVKYE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,433 days).
Specimen MP2PRT-PAVKYE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7066d53c-232e-4d81-b6df-7a84597c3cdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKYE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKYE-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abda4ee4-ed78-416b-91ee-18a2dd1f2010

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 44/227 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 55/274 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FAM81B | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs202064996, COSV51980413, COSV51987400; called by muse, mutect2, varscan2
- PNISR | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs1464723504; called by muse, mutect2, varscan2
- SETD1B | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1447040643, COSV57351074; called by muse, mutect2, varscan2
- SLITRK1 | c.1529C>G p.P510R | Missense Mutation (SNP) | VAF 115/265 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs757819524; called by muse, mutect2, varscan2
- CNNM1 | c.548T>A p.L183H | Missense Mutation (SNP) | VAF 33/626 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.473); called by muse, mutect2
- OR1S2 | c.405C>A p.H135Q | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIGLEC7 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF37A | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB8 | c.288A>C p.L96= (on ENST00000297504 / NM_001282291.2; = p.L79= on NM_007188.5) | Silent (SNP) | VAF 96/452 reads (21%) | called by muse, mutect2, varscan2
- CEP170B | c.1230C>T p.F410= (on ENST00000453495; = p.F339= on NM_015005.3) | Silent (SNP) | VAF 168/550 reads (31%) | catalogued as rs751471747, COSV69026722; called by muse, mutect2, varscan2
- TIGD2 | c.945G>A p.L315= | Silent (SNP) | VAF 61/398 reads (15%) | called by muse, mutect2, varscan2
- NLGN4Y | c.625+10258A>T | Intron (SNP) | VAF 38/49 reads (78%) | catalogued as rs1569370728; called by muse, mutect2, varscan2
